Somatic mutation profile of tumor specimen C3L-02508-02 (aliquot CPT0125810009) from CPTAC case C3L-02508, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 65.3 years (23,855 days).
Specimen C3L-02508-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44aa5957-9d97-4633-8880-2aaa4f87ac72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02508-32 (Blood Derived Normal), aliquot CPT0124270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f67ad5a2-c4b2-490b-86cc-50456091dd03

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Splice Region 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM227B | c.51+5G>T | Splice Region (SNP) | VAF 20/278 reads (7%) | catalogued as rs774870940; called by muse, mutect2
- KRT14 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 24/544 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as rs1450806388; called by muse, mutect2
- TECPR1 | c.2346G>A p.W782* | Nonsense Mutation (SNP) | VAF 10/194 reads (5%) | catalogued as rs1356400879; called by muse, mutect2
- VWC2 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV61484127; called by muse, mutect2
- WFS1 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 54/754 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs759466443; ClinVar: uncertain significance; called by muse, mutect2
- ATP8B3 | c.1136A>G p.N379S | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2
- MICU2 | c.210G>A p.Q70= | Splice Region (SNP) | VAF 20/347 reads (6%) | called by muse, mutect2
- PCNX2 | c.2798A>G p.Y933C | Missense Mutation (SNP) | VAF 19/374 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2
- STK31 | c.1712T>C p.V571A | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.039); called by muse, mutect2
- USP4 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.144); called by muse, mutect2
- CLU | c.1305G>A p.A435= | Silent (SNP) | VAF 38/614 reads (6%) | catalogued as rs148626219; called by muse, mutect2
- KLHL40 | c.126C>T p.R42= | Silent (SNP) | VAF 13/357 reads (4%) | catalogued as COSV55136563; called by muse, mutect2
